Somatic mutation profile of tumor specimen TARGET-10-PARGBR-09A (aliquot TARGET-10-PARGBR-09A-01D) from TARGET case TARGET-10-PARGBR, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.6 years (6,412 days).
Specimen TARGET-10-PARGBR-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5d14320-51c4-466f-ad0f-aecb66dc688f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARGBR-10A (Blood Derived Normal), aliquot TARGET-10-PARGBR-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e6d6db82-4662-494c-bffe-9b1d773292a8

The open-access MAF lists 28 somatic variants for this specimen: 16 protein-altering or splice-affecting, 7 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 7, Intron 3, 3'UTR 1, Frame Shift Ins 1, Frame Shift Del 1, Nonsense Mutation 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 34/63 reads (54%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACTL6A | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1398588309, COSV52022999; called by muse, mutect2, varscan2
- ADGRV1 | c.5162C>T p.T1721I | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1298138629; called by muse, mutect2, varscan2
- CSMD3 | c.3185C>A p.T1062N (on ENST00000297405 / NM_001363185.1; = p.T958N on NM_052900.3) | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.042); catalogued as COSV52128931; called by muse, mutect2
- DCX | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 39/41 reads (95%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as CM1313995, COSV57568865; called by muse, mutect2, varscan2
- PCSK2 | c.1219C>T p.R407W | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52732903; called by muse, mutect2, varscan2
- RBM25 | c.1237C>T p.R413* | Nonsense Mutation (SNP) | VAF 30/58 reads (52%) | catalogued as COSV56199898; called by muse, mutect2, varscan2
- TNK2 | c.1643T>C p.L548P | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.062); catalogued as rs1237496903; called by muse, mutect2, varscan2
- ALDH1L1 | c.1891T>A p.S631T | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- CACYBP | c.539C>G p.S180C | Missense Mutation (SNP) | VAF 71/169 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- CDC42BPG | c.4301C>G p.S1434C | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- CILP2 | c.2917C>T p.R973W | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP3K1 | c.1851dup p.A618Sfs*28 | Frame Shift Ins (INS) | VAF 16/34 reads (47%) | called by mutect2, varscan2
- MAP3K1 | c.1853_1854del p.A618Dfs*27 | Frame Shift Del (DEL) | VAF 16/32 reads (50%) | called by mutect2, pindel*, varscan2
- SCN1A | c.3857G>T p.W1286L (on ENST00000303395 / NM_001202435.3; = p.W1275L on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZRSR2 | c.824_827+2delinsCCG p.X275_splice | Splice Site (DEL) | VAF 41/43 reads (95%) | called by pindel, varscan2*
- FILIP1L | c.2652C>T p.A884= (on ENST00000354552 / NM_182909.3; = p.A644= on NM_014890.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 43/94 reads (46%) | called by muse, mutect2, varscan2
- GFRA1 | c.492C>T p.D164= | Silent (SNP) | VAF 32/57 reads (56%) | catalogued as rs79176106, COSV62607798; called by muse, mutect2, varscan2
- MSLN | c.1662C>T p.H554= (on ENST00000382862 / NM_013404.4; = p.H546= on NM_005823.6) | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as rs371032824; called by muse, mutect2, varscan2
- NPHS2 | c.1041G>T p.L347= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as COSV62634585; called by muse, mutect2, varscan2
- SNCAIP | c.1380C>T p.A460= | Silent (SNP) | VAF 36/73 reads (49%) | catalogued as rs769882967; called by muse, mutect2, varscan2
- ZNF516 | c.300G>A p.A100= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as rs1160441386, COSV101487388; called by mutect2, varscan2
- ZNF532 | c.804G>A p.S268= | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as rs767385026, COSV60171828; called by muse, mutect2, varscan2
- ERCC3 | c.28+85T>A | Intron (SNP) | VAF 6/9 reads (67%) | called by muse, varscan2
- IP6K1 | c.617-61G>A | Intron (SNP) | VAF 18/50 reads (36%) | called by muse, mutect2, varscan2
- PLOD1 | c.*87C>T | 3'UTR (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2
- RALYL | c.-24+607C>A | Intron (SNP) | VAF 21/49 reads (43%) | called by muse, mutect2, varscan2
- UBE3AP2 | n.489C>A | RNA (SNP) | VAF 26/59 reads (44%) | called by muse, mutect2, varscan2
